Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4G3, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4G3-01A (Primary Tumor).

[page 1 of 3]
Subject ID -

GROSS:

Specimen submitted: Distal gastrectomy, unfixed

Measurement: Greater curvature 20.6 cm

Lesser curvature 10.4 cm

Proximal resection margin 17.8 cm

Distal resection margin 5.2 cm

Duodenum 0.4 cm

Tumor location:

Stomach: Lower 1/3 (antrum), anterior wall

From proximal resection margin - 5.2 cm

From distal resection margin - 3.4 cm

Tumor size: 3.6 x 2.4 cm

Tumor type: AGC (Borrmann type) II

Gross serosal invasion: No

Representative sections are submitted

Blocks

T1-4, tumor and surrounding tissue x 4

A, antral mucosa x 1

B, body mucosa x 1

P, proximal resection margin x 1

D, distal resection margin x 1

DRM, labeled as 'distal margin' x 1

LN1-2, superior gastric lymph nodes x 2

LN3-4, inferior gastric lymph nodes x 2

LN5-6, '1' lymph nodes x 2

LN7, '4sb' lymph nodes x 1

LN8, '5' lymph nodes x 1

LN9-10, '6' lymph nodes x 2

LN11, '7' lymph nodes x 1 LN12, '8' lymph nodes x 1

LN13, '9' lymph nodes x 1 LN14, '11p' lymph nodes x 1

LN15, '12' lymph nodes x 1

MICROSCOPIC:

Tumor type: Adenocarcinoma, moderately differentiated, with partial adenosquamous carcinoma component

Depth of tumor invasion:

T2: Muscularis propria (MP)

Margins: Proximal resection margin (-)

Distal resection margin (-)

ICD-0-3

adenocarcinoma, tubular 8211/3

Site: Stomach, antrum C16.3

ju 9/27/12

[page 2 of 3]
Lauren classification: Intestinal

Ming classification (Growth pattern): Infiltrative

Lymphoid reaction: Present

Lymphovascular invasion: Present

Venous (large vessel) invasion: Absent

Perineural invasion: Absent

Lymph node metastases:

N2: Metastasis in 3-6 regional lymph nodes

number of involved nodes (5) total number of nodes (53)

perinodal extension: Yes

Distant metastasis(M):

MX: Distant metastasis cannot be assessed

Pathologic stage: pT2N2Mx (AJCC 7th edition)

DIAGNOSIS:

Stomach, distal gastrectomy:

Adenocarcinoma, moderately differentiated,

with partial adenosquamous carcinoma component, invasive

(advanced gastric cancer)

<Addendum>

Final diagnosis: Stomach Intestinal Adenocarcinoma, Tubular Type *per TSS classification*

Lymph node, perigastric, distal gastrectomy:

Superior gastric: Metastatic carcinoma, primary in stomach (1/2)

Inferior gastric: No tumor present (0/5)

Lymph node, regional, biopsy:

Labeled '1': No tumor present (0/9)

Labeled '4sb': Fibrofatty tissue

Labeled '5': Metastatic carcinoma, primary in stomach (1/2)

with extranodal tumor extension

Labeled '6': Metastatic carcinoma, primary in stomach (1/11)

Labeled '7': No tumor present (0/6)

Labeled '8': Metastatic carcinoma, primary in stomach (1/5)

Labeled '9': No tumor present (0/5)

Labeled '11p': Metastatic carcinoma, primary in stomach (1/6)

Labeled '12': No tumor present (0/2)

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): Stomach adenocarcinoma

Completed By _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Stomach Intestinal Adenocarcinoma w/Partial Adenosquamous Component	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF	Stomach Intestinal Adenocarcinoma, Tubular Type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	In original pathology report for the resected specimen, partial squamous component was mentioned. Review of top slide of the sample submitted to TCGA revealed no squamous component.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file d28c54cb-5ad6-4077-be91-ee85f0b42553 (TCGA-HU-A4G3.06D3E692-3EE0-4CA0-B1A0-FFC24A8B6F2B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).